Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7055, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7055-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Analysis & History:

with incidental left renal mass discovered on CT

Specimens Submitted:

- 1: Kidney, left mass, partial nephrectomy
- 2: Kidney, left, completion nephrectomy
- 3: Perinephric fat, left, excision

DIAGNOSIS:

1. Kidney, left mass, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Unclassified type

The tumor has oncocytic, tubular and papillary features

Tumor Size:

Greatest diameter is 3.8 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: Immunohistochemical stains show the tumor cells to be strongly positive for E-cadherin and CD117, positive for Ca-9 and racemase and negative for CK7.

2. Kidney, left, completion nephrectomy:

-No residual carcinoma is identified.

-Unremarkable renal parenchyma

-Incidental medullary fibroma (0.2cm) is identified

[page 2 of 3]
- Unremarkable urothelium
-Unremarkable renal vessels

3. Perinephric fat, left, excision:
-Benign fibroadipose tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

Special Studies:

Result	Special Stain	Comment
	CK7	
	CA-1X	
	RACEMASE	
	E-CADHERIN	
	CD117	
	NEG CONT	
	IMM RECUT	

Gross Description:

1). The specimen is received fresh for frozen section, labeled "left renal mass". It consists of a 6.0 x 5.0 x 2.8 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a 3.8 x 3.5 x 3.0 cm. The clearance from the resection margin is 0.1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control
T - tumor
RS - representative sections

2). The specimen is received fresh, labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 162 g in total. The kidney measures 12.0 x 5.5 x 3.4 cm. The attached ureter measures 8.0 cm in length and 0.2 cm in diameter. The attached renal vein measures 1.5 cm in length and 0.8 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. There is a central surgical defect in the kidney measuring 7.5 x 5.0 x 2.5 cm. The kidney is bivalved to reveal a 0.2 x 0.2 x 0.2 cm well defined gray-white firm focus located in the medulla in the upper pole. The remaining kidney shows pink-brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.5 cm and the calyces appear normal. There are no other lesions identified. There are no lymph nodes identified in the perinephric fat. Representative sections are submitted.

Summary of sections:

UVM -- ureteral and vessel margins
F -- 0.2 cm focus
D--surgical defect
RP -- renal pelvis representative sections
K -- representative sections kidney

3). The specimen is received fresh, labeled "peri-nephric fat, left" and consists of multiple pieces of adipose tissue measuring 12.0 x 10.5 x 3.5 cm in aggregate. No tumor or lymph nodes identified. Representative sections are submitted

Summary of sections:

[page 3 of 3]
F-- adipose tissue

Summary of Sections:

Part 1: Kidney, left mass, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
2	rs	2
4	t	4

Part 2: Kidney, left, completion nephrectomy

Block	Sect. Site	PCs
3	d	3
1	f	1
1	k	1
1	rp	1
1	uvm	1

Part 3: Perinephric fat, left, excision

Block	Sect. Site	PCs
1	f	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: LEFT RENAL MASS [REDACTED] ONCOCYTIC RENAL CORTICAL
NEOPLASM. MARGIN IS CLOSE, BUT NEGATIVE [REDACTED]
PERMANENT DIAGNOSIS: same [REDACTED]

Source: NCI Genomic Data Commons file 7a1895a5-068e-4738-a666-a15bf98f026c (TCGA-BQ-7055.68AD1972-D23F-4647-BFF1-49053F7BE848.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).